Somatic mutation profile of tumor specimen ALCH-B24Z-TTP1-A (aliquot ALCH-B24Z-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B24Z, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.4 years (24,261 days).
Specimen ALCH-B24Z-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83b481c2-13dc-4a00-a09a-6acb9099229d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B24Z-NB1-A (Blood Derived Normal), aliquot ALCH-B24Z-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d719bf3c-33b5-47a3-80d7-12d73b553974

The open-access MAF lists 430 somatic variants for this specimen: 298 protein-altering or splice-affecting, 71 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 265, Silent 71, Intron 28, Nonsense Mutation 18, RNA 12, 3'UTR 10, Frame Shift Del 5, 5'UTR 5, Splice Region 4, Splice Site 4, 5'Flank 4, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3008A>G p.Y1003C | Missense Mutation (SNP) | VAF 69/282 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV100577167, COSV59258910, COSV59262717; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 72/209 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM5 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 110/347 reads (32%) | catalogued as COSV59370793; called by muse, mutect2, varscan2
- ADAM2 | c.15G>T p.L5F | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.279); catalogued as rs774922405; called by muse, mutect2, varscan2
- ADAMTS18 | c.2498C>T p.A833V | Missense Mutation (SNP) | VAF 61/282 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147816593; called by muse, mutect2, varscan2
- ADAR | c.1405G>T p.A469S | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); catalogued as rs886045343, COSV99425542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFTPH | c.499C>A p.Q167K | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs1362508938; called by muse, mutect2, varscan2
- AIFM3 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150271585; called by muse, mutect2
- ANO4 | c.931C>A p.H311N (on ENST00000392977 / NM_001286615.2; = p.H276N on NM_178826.4) | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.801); catalogued as COSV54609635; called by muse, mutect2, varscan2
- AQP9 | c.349del p.A117Lfs*21 | Frame Shift Del (DEL) | VAF 27/147 reads (18%) | catalogued as rs779708932; called by mutect2, pindel, varscan2
- ARHGAP9 | c.1014dup p.R339Afs*17 | Frame Shift Ins (INS) | VAF 15/162 reads (9%) | catalogued as rs771769575; called by mutect2, pindel
- ATP10A | c.2864C>A p.S955Y | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.222); catalogued as COSV63515179; called by muse, mutect2, varscan2
- BMPER | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 127/541 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1483511272, COSV51819417; called by muse, mutect2, varscan2
- BOD1L2 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); catalogued as COSV73996954; called by muse, mutect2
- BRINP3 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV66533544; called by muse, mutect2, varscan2
- CAVIN4 | c.979C>A p.P327T | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV56866461; called by muse, mutect2, varscan2
- CCDC88B | c.1283G>C p.R428P | Missense Mutation (SNP) | VAF 54/316 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57265681; called by muse, mutect2, varscan2
- CDH10 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52570603, COSV52576617; called by muse, mutect2, varscan2
- CFHR4 | c.1439C>A p.S480* (on ENST00000367416 / NM_001201551.2; = p.S234* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 101/925 reads (11%) | catalogued as COSV52224510; called by muse, mutect2, varscan2
- CHIA | c.793C>G p.P265A (on ENST00000343320; = p.P157A on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.948); catalogued as COSV58474552, COSV58475901; called by muse, mutect2, varscan2
- COL19A1 | c.1933C>A p.P645T | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs751493605; called by muse, mutect2, varscan2
- COL4A4 | c.3514G>T p.G1172* | Nonsense Mutation (SNP) | VAF 111/393 reads (28%) | catalogued as rs1364773011, COSV104395237; called by muse, mutect2, varscan2
- CSMD3 | c.3848C>A p.A1283D (on ENST00000297405 / NM_001363185.1; = p.A1179D on NM_052900.3) | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52176973, COSV99820986; called by muse, mutect2, varscan2
- DCK | c.104C>A p.S35* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as rs1482976727; called by muse, mutect2, varscan2
- DEFB116 | c.241G>T p.V81L | Missense Mutation (SNP) | VAF 33/261 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV101269251; called by muse, varscan2
- DOCK7 | c.5251G>T p.V1751F (on ENST00000635253 / NM_001367561.1; = p.V1720F on NM_033407.3) | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV51995077; called by muse, mutect2, varscan2
- DOCK7 | c.2500G>A p.G834R | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.323); catalogued as rs147710829; called by muse, mutect2, varscan2
- DOCK7 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762552417; called by muse, mutect2, varscan2
- DPP10 | c.2163A>G p.I721M | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59709297; called by muse, mutect2, varscan2
- DSCAM | c.422C>A p.A141E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV68652155; called by muse, mutect2, varscan2
- EEF2 | c.2180G>T p.R727L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV58579822; called by muse, mutect2, varscan2
- EXOC4 | c.2813G>A p.G938E | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV99553393, COSV99553758; called by muse, mutect2, varscan2
- FAAP100 | c.1705G>T p.V569L | Missense Mutation (SNP) | VAF 86/270 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV59884275; called by muse, mutect2, varscan2
- FAM135B | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 94/223 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.795); catalogued as rs2978180; called by muse, mutect2, varscan2
- FANCM | c.1718del p.R573Qfs*13 | Frame Shift Del (DEL) | VAF 47/164 reads (29%) | catalogued as COSV57502390, COSV57502808; called by mutect2, pindel, varscan2
- FBLN2 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1175308472, COSV55490831; called by muse, mutect2, varscan2
- FER1L6 | c.4768C>A p.P1590T | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67549225; called by muse, mutect2, varscan2
- FNDC1 | c.3848C>A p.T1283K | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.705); catalogued as COSV51939560; called by muse, mutect2, varscan2
- GABRA4 | c.1312C>A p.R438S | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs201220260; called by muse, mutect2, varscan2
- GCN1 | c.5212G>A p.E1738K | Missense Mutation (SNP) | VAF 100/319 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.552); catalogued as COSV56114947; called by muse, mutect2, varscan2
- GLIPR1L2 | c.927G>T p.E309D | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.391); catalogued as COSV101097427; called by muse, mutect2, varscan2
- GNA11 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs780718032, COSV99030242; called by muse, mutect2, varscan2
- GNAL | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs778292731; called by muse, mutect2, varscan2
- GRIP2 | c.3316G>A p.A1106T (on ENST00000619221; = p.A1009T on NM_001080423.4) | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.782); catalogued as rs777582626; called by muse, mutect2, varscan2
- HOXB2 | c.272C>A p.P91Q | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as rs544258654; called by muse, varscan2
- HOXD13 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1435965440, COSV66832416; called by muse, varscan2
- ING4 | c.362A>G p.Y121C | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.662); catalogued as rs374543463; called by muse, mutect2, varscan2
- KCNV1 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.795); catalogued as rs1330130704; called by muse, mutect2, varscan2
- KEAP1 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 87/321 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50260458, COSV50275012, COSV50315065; called by muse, mutect2, varscan2
- LAMA1 | c.8084G>A p.R2695Q | Missense Mutation (SNP) | VAF 66/296 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs558634642, COSV67540894; called by muse, mutect2, varscan2
- LRGUK | c.2294C>G p.S765C | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.533); catalogued as COSV99603690; called by muse, mutect2, varscan2
- LRRC4C | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs768399802, COSV53421139, COSV53435466; called by muse, mutect2, varscan2
- MAGEC1 | c.1297A>G p.S433G | Missense Mutation (SNP) | VAF 98/292 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs772957635; called by muse, varscan2
- MECP2 | c.859G>C p.A287P | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs61750257, CD003790, CX045726; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MMS22L | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs759302016; called by muse, varscan2
- MOCS1 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 71/443 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51342314; called by muse, mutect2, varscan2
- MRC1 | c.3214G>A p.D1072N | Missense Mutation (SNP) | VAF 16/507 reads (3%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.462); catalogued as rs966584729; called by muse, mutect2
- MYH1 | c.3528G>C p.Q1176H | Missense Mutation (SNP) | VAF 81/538 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs1342538829; called by muse, mutect2, varscan2
- NCOA1 | c.2443G>T p.D815Y | Missense Mutation (SNP) | VAF 60/329 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1294726152; called by muse, mutect2, varscan2
- NDUFS2 | c.583G>C p.G195R | Missense Mutation (SNP) | VAF 81/363 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100917495; called by muse, mutect2, varscan2
- NEUROG1 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 60/271 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59082211; called by muse, mutect2, varscan2
- NOVA1 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.269); catalogued as rs1434253680; called by muse, varscan2
- NR1I2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 84/396 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1412966426, COSV61977986; called by muse, mutect2, varscan2
- NUAK1 | c.632C>G p.T211R | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394535554, COSV99777404; called by muse, mutect2, varscan2
- OR2A12 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 33/346 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.02); catalogued as rs779197185; called by muse, mutect2
- OR4A15 | c.288G>T p.M96I | Missense Mutation (SNP) | VAF 55/314 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); catalogued as COSV100123916; called by muse, mutect2, varscan2
- OR4K5 | c.217C>G p.Q73E | Missense Mutation (SNP) | VAF 93/172 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV60005516; called by muse, mutect2, varscan2
- OTOG | c.1651G>A p.V551M | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs556550974; called by muse, mutect2, varscan2
- PCDHA10 | c.1897A>T p.T633S | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.304); catalogued as COSV56520648; called by muse, mutect2, varscan2
- PCDHA8 | c.1447G>C p.D483H | Missense Mutation (SNP) | VAF 171/575 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100971010; called by muse, mutect2, varscan2
- PCDHA9 | c.1723G>T p.G575C | Missense Mutation (SNP) | VAF 125/332 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as COSV100969102; called by muse, mutect2, varscan2
- PDE6A | c.1660C>A p.R554S | Missense Mutation (SNP) | VAF 111/375 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV54927419, COSV99678552; called by muse, mutect2, varscan2
- PLCB1 | c.1364C>G p.P455R | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62057721; called by muse, mutect2
- POLDIP3 | c.1139G>T p.R380M | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99349462; called by muse, mutect2, varscan2
- POTEC | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 168/595 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV62801215; called by muse, mutect2, varscan2
- PROS1 | c.1997G>T p.C666F | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1298945000; called by muse, mutect2, varscan2
- PRR14 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.424); catalogued as COSV99788469; called by muse, mutect2, varscan2
- PRTG | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs367914044; called by muse, mutect2, varscan2
- PSMA7 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1568728760; called by muse, mutect2, varscan2
- PTPRN2 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs151334443, COSV67035394; called by muse, mutect2, varscan2
- RIN2 | c.1183G>T p.V395L (on ENST00000255006 / NM_001242581.1; = p.V346L on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV99657469; called by muse, mutect2
- SALL1 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs750514153, COSV51760431, COSV51762914; called by muse, mutect2, varscan2
- SDR39U1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 54/194 reads (28%) | catalogued as rs188940530, COSV52163322; called by muse, mutect2, varscan2
- SENP7 | c.2861G>C p.R954P | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58607532; called by muse, mutect2, varscan2
- SIPA1 | c.1276C>A p.R426S | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs765842608; called by muse, mutect2, varscan2
- SLC43A3 | c.1270A>C p.K424Q | Missense Mutation (SNP) | VAF 88/296 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758870554; called by muse, mutect2, varscan2
- SLITRK4 | c.2140C>G p.P714A | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as COSV62021954; called by muse, mutect2, varscan2
- SPANXN2 | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.989); catalogued as COSV65128943; called by muse, varscan2
- SPOPL | c.1068G>A p.W356* | Nonsense Mutation (SNP) | VAF 28/192 reads (15%) | catalogued as COSV99699546; called by muse, mutect2, varscan2
- STK10 | c.1826T>A p.F609Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1561799642; called by muse, mutect2
- TAAR2 | c.745A>T p.N249Y (on ENST00000367931 / NM_001033080.1; = p.N204Y on NM_014626.3) | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs769677016; called by muse, varscan2
- TCERG1L | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1389429611; called by muse, mutect2, varscan2
- TENM1 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs140628958; called by muse, mutect2, varscan2
- TET2 | c.3823G>T p.G1275W | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54417605; called by muse, mutect2
- TGIF2LX | c.145C>A p.H49N | Missense Mutation (SNP) | VAF 110/326 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.045); catalogued as COSV99383256; called by muse, mutect2, varscan2
- TGIF2LY | c.320G>C p.R107P | Missense Mutation (SNP) | VAF 168/398 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58291604; called by muse, mutect2, varscan2
- TNXB | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746485634; called by muse, mutect2, varscan2
- TRIM48 | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 102/426 reads (24%) | catalogued as COSV70161976; called by muse, mutect2, varscan2
- TRIM51 | c.353C>A p.S118Y | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99793263; called by muse, mutect2, varscan2
- TTN | c.99238G>T p.E33080* (on ENST00000591111; = p.E25656* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 20/175 reads (11%) | catalogued as COSV60378796; called by muse, varscan2
- TTN | c.99237G>T p.E33079D (on ENST00000591111; = p.E25655D on NM_003319.4) | Missense Mutation (SNP) | VAF 20/178 reads (11%) | PolyPhen benign (0.003); catalogued as COSV59915214; called by muse, varscan2
- UBOX5 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 56/355 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs1462523072, COSV99417416; called by muse, mutect2, varscan2
- VEGFD | c.973T>C p.C325R | Missense Mutation (SNP) | VAF 123/241 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs753345485; called by muse, mutect2, varscan2
- VWA5B2 | c.2698C>A p.Q900K | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs894321838; called by muse, mutect2, varscan2
- WDPCP | c.256C>A p.R86= | Splice Region (SNP) | VAF 34/388 reads (9%) | catalogued as COSV55430355; called by muse, mutect2
- WDR91 | c.26A>T p.D9V | Missense Mutation (SNP) | VAF 85/382 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771606045; called by muse, mutect2, varscan2
- ZDBF2 | c.787C>A p.R263S | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV65627553; called by muse, varscan2
- ZNF257 | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780779622; called by muse, mutect2
- ZNF264 | c.539A>G p.D180G | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs538601627; called by muse, varscan2
- ZNF568 | c.1738C>A p.H580N | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61740605; called by muse, mutect2, varscan2
- ZNF99 | c.2198A>G p.Y733C | Missense Mutation (SNP) | VAF 79/386 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773786823; called by muse, mutect2, varscan2
- ABCA10 | c.1522-2A>T p.X508_splice | Splice Site (SNP) | VAF 46/142 reads (32%) | called by muse, mutect2, varscan2
- ACSM5 | c.748G>C p.G250R | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ACTRT3 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ADARB2 | c.938A>G p.D313G | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- ADGRE2 | c.685T>G p.C229G | Missense Mutation (SNP) | VAF 43/352 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ADGRL3 | c.847G>A p.D283N (on ENST00000506720 / NM_001322402.2; = p.D215N on NM_015236.6) | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AEN | c.421G>T p.V141F | Missense Mutation (SNP) | VAF 82/340 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- AIPL1 | c.638C>G p.T213S | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ALPK1 | c.2381G>A p.S794N | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AMPH | c.1749G>T p.E583D | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- AOX1 | c.3400A>G p.I1134V | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ARHGAP6 | c.1382G>T p.S461I | Missense Mutation (SNP) | VAF 61/108 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ASB2 | c.634G>T p.G212* | Nonsense Mutation (SNP) | VAF 139/332 reads (42%) | called by muse, mutect2, varscan2
- ASH1L | c.6937A>G p.K2313E (on ENST00000368346 / NM_001366177.2; = p.K2308E on NM_018489.3) | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ATG9B | c.618T>A p.N206K | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ATP10A | c.4007C>T p.T1336I | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- B3GALNT1 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 38/445 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- C9 | c.1433A>T p.N478I | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CA10 | c.763A>T p.K255* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- CA8 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 129/358 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CAMK2G | c.714G>A p.W238* | Nonsense Mutation (SNP) | VAF 52/172 reads (30%) | called by muse, mutect2, varscan2
- CASP8 | c.487G>T p.V163F (on ENST00000432109 / NM_033355.3; = p.V195F on NM_001228.4) | Missense Mutation (SNP) | VAF 101/379 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CCNJL | c.693G>T p.E231D | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- CDK14 | c.722T>A p.L241Q (on ENST00000380050 / NM_001287135.2; = p.L223Q on NM_012395.3) | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CERS6 | c.727G>C p.A243P | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP206 | c.485G>A p.S162N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHD5 | c.2513C>A p.S838Y | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CNBD1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP5 | c.3349G>T p.D1117Y | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL1A2 | c.3525T>A p.S1175R | Missense Mutation (SNP) | VAF 91/448 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- COL6A5 | c.5454C>G p.D1818E (on ENST00000312481; = p.D1814E on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPO | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CRPPA | c.818C>T p.A273V (on ENST00000407010 / NM_001368197.1; = p.A223V on NM_001101417.4) | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CSMD1 | c.7211G>A p.S2404N (on ENST00000520002; = p.S2403N on NM_033225.6) | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CST5 | c.381del p.W128Gfs*8 | Frame Shift Del (DEL) | VAF 38/179 reads (21%) | called by mutect2, pindel, varscan2
- CYP4F22 | c.518A>G p.K173R | Missense Mutation (SNP) | VAF 151/598 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- DCHS1 | c.4120G>C p.D1374H | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DDX3Y | c.1799A>G p.Y600C | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, varscan2
- DHX57 | c.4072A>G p.K1358E | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH17 | c.10134G>A p.M3378I | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAI4 | c.2419del p.L807Ffs*3 | Frame Shift Del (DEL) | VAF 28/114 reads (25%) | called by mutect2, pindel, varscan2
- DSEL | c.3637G>C p.D1213H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- DYNC1H1 | c.1126A>T p.R376W | Missense Mutation (SNP) | VAF 212/449 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNC1I1 | c.1919C>A p.T640N | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- EBF1 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- EEFSEC | c.1133A>G p.Q378R | Missense Mutation (SNP) | VAF 322/860 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- EFCC1 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EMID1 | c.566C>G p.P189R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EPHB1 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EVC2 | c.2370G>T p.Q790H | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- F9 | c.1269T>A p.S423R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- FAM180B | c.470G>T p.W157L | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- FANCM | c.5714C>A p.T1905K | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- FANCM | c.5715A>C p.T1905= | Splice Region (SNP) | VAF 25/119 reads (21%) | called by muse, mutect2, varscan2
- FBN2 | c.7347T>C p.D2449= | Splice Region (SNP) | VAF 74/258 reads (29%) | called by muse, mutect2, varscan2
- FCRL3 | c.1527G>T p.W509C | Missense Mutation (SNP) | VAF 65/493 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- FNDC1 | c.2717G>T p.W906L | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- FREM3 | c.4159T>C p.Y1387H | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRMD7 | c.778A>C p.S260R | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FRMPD1 | c.4194C>A p.H1398Q | Missense Mutation (SNP) | VAF 142/333 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- FSHR | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- FSIP2 | c.742C>A p.R248S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- GAB4 | c.1288G>T p.A430S | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.024); called by muse, varscan2
- GAL3ST4 | c.926A>T p.E309V | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- GALNT13 | c.1321T>G p.C441G | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- GALNT13 | c.1616G>A p.C539Y | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GARRE1 | c.306C>A p.S102R | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- GRAMD1B | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- GREB1 | c.5483T>A p.L1828Q | Missense Mutation (SNP) | VAF 85/311 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- GRM8 | c.1193A>T p.Q398L | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- GUCY1A2 | c.1404G>C p.R468S | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- H4C4 | c.133A>G p.K45E | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- HBG2 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 61/984 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- HEPH | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HPN | c.1102C>G p.R368G | Missense Mutation (SNP) | VAF 86/407 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HPX | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 64/434 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR1F | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- IGKV1-9 | c.242C>A p.P81Q | Missense Mutation (SNP) | VAF 136/497 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- IGLV4-3 | c.285C>G p.Y95* | Nonsense Mutation (SNP) | VAF 43/338 reads (13%) | called by muse, mutect2, varscan2
- IGLV9-49 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ISM1 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 87/283 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); called by muse, varscan2
- ITIH4 | c.844A>T p.S282C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITK | c.454+1G>T p.X152_splice | Splice Site (SNP) | VAF 63/216 reads (29%) | called by muse, varscan2
- JAG1 | c.1288C>G p.L430V | Missense Mutation (SNP) | VAF 44/562 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- KALRN | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 70/800 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- KCNB2 | c.2522G>T p.G841V | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- KIAA1109 | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF25 | c.784C>G p.Q262E | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KIR3DL1 | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KRT24 | c.1360G>T p.G454C | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- LRBA | c.8002C>A p.L2668M | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRMDA | c.44A>T p.K15I | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- LRP1B | c.11404G>T p.E3802* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2
- LRRC63 | c.433del p.R145Gfs*2 | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | called by mutect2, varscan2
- LRRK2 | c.6377C>A p.A2126D | Missense Mutation (SNP) | VAF 51/273 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- MACF1 | c.5401G>A p.D1801N | Missense Mutation (SNP) | VAF 52/157 reads (33%) | called by muse, mutect2, varscan2
- MAGEC1 | c.2143C>G p.P715A | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- MAGI3 | c.1359A>T p.P453= | Splice Region (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- MINDY2 | c.724G>T p.V242L | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MROH2B | c.2510T>A p.L837Q | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MTM1 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 95/200 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MTRNR2L7 | c.8C>A p.T3K | Missense Mutation (SNP) | VAF 19/93 reads (20%) | PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MTX2 | c.742A>T p.R248* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- MYO10 | c.4820A>C p.Y1607S | Missense Mutation (SNP) | VAF 139/511 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NLRP14 | c.2288T>C p.L763P | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- NPR3 | c.908A>G p.K303R | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR14A2 | c.667G>T p.V223L | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR2T12 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 60/351 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2T6 | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.006); called by muse, mutect2
- OR51Q1 | c.572G>C p.C191S | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OR52N4 | c.866C>T p.T289I | Missense Mutation (SNP) | VAF 44/407 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- OR56A3 | c.400C>A p.L134M | Missense Mutation (SNP) | VAF 61/574 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAGE1 | c.212C>A p.T71N | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- PANK1 | c.415G>C p.G139R | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAPPA | c.3734G>T p.G1245V | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PCDHGA2 | c.2294A>G p.K765R | Missense Mutation (SNP) | VAF 141/420 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHGB3 | c.4G>C p.G2R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- PCLO | c.3113C>T p.A1038V | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCOLCE2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 19/88 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- PIGO | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIK3R2 | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, varscan2
- PKHD1 | c.3515A>T p.H1172L | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PPP4R3B | c.1700T>C p.M567T | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- PRKAR2A | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PTPRB | c.5124G>C p.E1708D | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2
- PYGM | c.595C>A p.L199I | Missense Mutation (SNP) | VAF 156/627 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RBM19 | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBMXL3 | c.487A>T p.K163* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- REST | c.2095G>C p.A699P | Missense Mutation (SNP) | VAF 59/308 reads (19%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.029); called by muse, varscan2
- RNF168 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.074); called by muse, mutect2
- RWDD2A | c.41T>A p.L14Q | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- S100PBP | c.509A>G p.D170G | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- SCML4 | c.382T>A p.S128T | Missense Mutation (SNP) | VAF 70/346 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SCT | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SEMA6C | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SEPHS1 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SF3B4 | c.1053G>T p.M351I | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- SHOX2 | c.738G>T p.Q246H (on ENST00000441443 / NM_006884.3; = p.Q270H on NM_003030.4) | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, varscan2
- SI | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SIPA1 | c.1277G>C p.R426P | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIPA1L3 | c.1749G>T p.K583N | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- SLC26A8 | c.1959C>A p.S653R | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- SLC2A3 | c.1068+1G>T p.X356_splice | Splice Site (SNP) | VAF 38/326 reads (12%) | called by muse, mutect2, varscan2
- SLC36A3 | c.410C>A p.T137N | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- SLC9C1 | c.1784C>A p.P595Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SLITRK5 | c.1528C>A p.L510I | Missense Mutation (SNP) | VAF 80/310 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SMG7 | c.62-1G>C p.X21_splice | Splice Site (SNP) | VAF 28/108 reads (26%) | called by muse, mutect2, varscan2
- SOHLH1 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 126/543 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- SORBS1 | c.2954C>A p.T985N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SOX30 | c.1940A>G p.E647G (on ENST00000265007 / NM_178424.2; = p.N483D on NM_007017.2) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); called by mutect2, varscan2
- SPANXB1 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 163/736 reads (22%) | SIFT tolerated, low confidence (0.39); called by muse, mutect2, varscan2
- SPATA18 | c.866A>G p.N289S | Missense Mutation (SNP) | VAF 72/347 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPATA31A3 | c.2743C>A p.P915T | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- SPATA31A6 | c.1820G>A p.W607* | Nonsense Mutation (SNP) | VAF 33/95 reads (35%) | called by mutect2, varscan2
- SPTAN1 | c.6812C>T p.A2271V | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- TAF1L | c.4275C>A p.H1425Q | Missense Mutation (SNP) | VAF 88/487 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- TEX14 | c.518T>C p.V173A | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TGFBR3L | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TGIF2LX | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 169/377 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- TMEM214 | c.1126A>C p.S376R | Missense Mutation (SNP) | VAF 64/281 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- TMEM216 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM232 | c.1028A>G p.E343G | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by mutect2, varscan2
- TNN | c.550G>T p.G184W | Missense Mutation (SNP) | VAF 70/328 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRH | c.487G>C p.A163P | Missense Mutation (SNP) | VAF 45/434 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- TRPC4 | c.628G>C p.A210P | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC23L | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TTC29 | c.503A>T p.K168M | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- TTI1 | c.1217G>A p.G406D | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.7037C>T p.T2346I (on ENST00000591111; = p.T2300I on NM_003319.4) | Missense Mutation (SNP) | VAF 71/382 reads (19%) | PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TTN | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 126/569 reads (22%) | PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TXNL1 | c.311A>G p.K104R | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.144); called by muse, varscan2
- UBD | c.143A>C p.Q48P | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- UNC13C | c.2719C>G p.H907D | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP11 | c.2033A>C p.D678A (on ENST00000218348; = p.D635A on NM_001371072.1) | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- USP13 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP17L2 | c.21C>G p.Y7* | Nonsense Mutation (SNP) | VAF 111/442 reads (25%) | called by muse, mutect2
- WDR86 | c.869C>A p.T290K | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- WDR87 | c.4765G>T p.A1589S | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WT1 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 109/250 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WWOX | c.938C>A p.P313Q | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- XPNPEP2 | c.1053G>A p.M351I | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- ZNF521 | c.3791T>A p.V1264E | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF578 | c.348G>T p.Q116H | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF618 | c.591C>A p.Y197* (on ENST00000374126 / NM_001318042.2; = p.Y165* on NM_133374.2) | Nonsense Mutation (SNP) | VAF 39/200 reads (20%) | called by muse, mutect2, varscan2
- ZNF766 | c.526C>A p.Q176K | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN5B | c.1049A>T p.K350M | Missense Mutation (SNP) | VAF 84/444 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZWILCH | c.1568A>T p.Y523F | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM7 | c.1506G>A p.G502= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as COSV99445115; called by muse, mutect2, varscan2
- ANKRD45 | c.153G>A p.L51= | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as COSV60960856; called by muse, mutect2, varscan2
- ARFIP2 | c.12G>A p.G4= | Silent (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2
- ARSJ | c.1392C>T p.S464= | Silent (SNP) | VAF 17/204 reads (8%) | called by muse, mutect2
- ASTN2 | c.627G>T p.V209= | Silent (SNP) | VAF 32/206 reads (16%) | catalogued as COSV57818940; called by muse, mutect2, varscan2
- BRCA2 | c.2766C>T p.F922= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as rs764749018; called by muse, varscan2
- C3orf52 | c.18C>T p.P6= | Silent (SNP) | VAF 18/184 reads (10%) | called by muse, mutect2
- CAPN9 | c.1650G>T p.L550= | Silent (SNP) | VAF 44/217 reads (20%) | called by muse, mutect2, varscan2
- CCDC88B | c.1284G>T p.R428= | Silent (SNP) | VAF 55/313 reads (18%) | catalogued as COSV57265684; called by muse, mutect2, varscan2
- CDK5RAP2 | c.876C>T p.I292= | Silent (SNP) | VAF 71/296 reads (24%) | called by muse, mutect2, varscan2
- COL19A1 | c.2274T>A p.P758= | Silent (SNP) | VAF 57/161 reads (35%) | called by muse, varscan2
- COL6A5 | c.1638C>T p.Y546= | Silent (SNP) | VAF 35/402 reads (9%) | catalogued as rs1484916070; called by muse, mutect2
- COL9A1 | c.534C>A p.S178= | Silent (SNP) | VAF 19/183 reads (10%) | called by muse, mutect2, varscan2
- CPA3 | c.1140A>T p.R380= | Silent (SNP) | VAF 17/91 reads (19%) | called by muse, varscan2
- CR1 | c.5067G>A p.A1689= | Silent (SNP) | VAF 18/298 reads (6%) | catalogued as rs1192219537, COSV65459262; called by muse, mutect2
- CYLC1 | c.324C>A p.T108= | Silent (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- DNAH11 | c.4636C>T p.L1546= | Silent (SNP) | VAF 55/280 reads (20%) | catalogued as rs1443814276, COSV100178664; called by muse, mutect2, varscan2
- DOCK10 | c.1533C>A p.I511= | Silent (SNP) | VAF 39/133 reads (29%) | catalogued as COSV51390709; called by muse, mutect2, varscan2
- DPP10 | c.705C>A p.L235= | Silent (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2
- FAAH | c.52C>T p.L18= | Silent (SNP) | VAF 38/138 reads (28%) | called by muse, mutect2, varscan2
- FBN3 | c.1140C>A p.L380= | Silent (SNP) | VAF 29/150 reads (19%) | called by muse, mutect2, varscan2
- FIGNL2 | c.708C>A p.P236= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- FOXN4 | c.702C>A p.P234= | Silent (SNP) | VAF 28/172 reads (16%) | catalogued as COSV54495431; called by muse, mutect2
- GAL3ST3 | c.1263C>A p.I421= | Silent (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- GASK1A | c.1158C>T p.N386= | Silent (SNP) | VAF 57/170 reads (34%) | called by muse, mutect2, varscan2
- GLRA4 | c.258C>T p.T86= | Silent (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.690A>G p.L230= | Silent (SNP) | VAF 43/186 reads (23%) | called by muse, mutect2, varscan2
- GOLGB1 | c.7476G>A p.L2492= | Silent (SNP) | VAF 33/127 reads (26%) | called by muse, mutect2, varscan2
- GPX5 | c.621C>T p.V207= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs1393756719, COSV69079811; called by muse, mutect2, varscan2
- HAUS1 | c.834G>T p.L278= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV99959385; called by muse, mutect2, varscan2
- HERC2 | c.7842A>G p.K2614= | Silent (SNP) | VAF 29/89 reads (33%) | called by muse, mutect2, varscan2
- HMGN4 | c.234C>T p.L78= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- HOXC10 | c.822C>T p.P274= | Silent (SNP) | VAF 41/249 reads (16%) | called by muse, mutect2, varscan2
- IBA57 | c.951G>T p.V317= | Silent (SNP) | VAF 32/144 reads (22%) | called by muse, mutect2, varscan2
- IL17A | c.129G>T p.R43= | Silent (SNP) | VAF 37/365 reads (10%) | catalogued as COSV100391586; called by muse, mutect2
- ISG20 | c.513C>T p.R171= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as rs780938636, COSV60144434; called by muse, mutect2, varscan2
- KIAA1549 | c.4626C>T p.R1542= | Silent (SNP) | VAF 45/284 reads (16%) | catalogued as rs577570180, COSV54323400; called by muse, mutect2, varscan2
- KIF12 | c.1326C>T p.S442= (on ENST00000640217; = p.S304= on NM_138424.1) | Silent (SNP) | VAF 67/341 reads (20%) | catalogued as rs374703826; called by muse, mutect2, varscan2
- KRTAP9-1 | c.621G>A p.E207= | Silent (SNP) | VAF 67/486 reads (14%) | called by muse, mutect2, varscan2
- LRRC7 | c.2919A>T p.L973= (on ENST00000651989 / NM_001370785.2; = p.L940= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 44/166 reads (27%) | called by muse, mutect2, varscan2
- MCTP2 | c.669G>A p.L223= | Silent (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- MEIS2 | c.396C>T p.A132= (on ENST00000561208 / NM_170675.5; = p.A119= on NM_002399.3) | Silent (SNP) | VAF 61/363 reads (17%) | catalogued as rs1286820299; called by muse, mutect2, varscan2
- MRGPRX1 | c.156G>T p.L52= | Silent (SNP) | VAF 34/177 reads (19%) | catalogued as rs773224686; called by muse, mutect2, varscan2
- MUC16 | c.42597G>T p.R14199= | Silent (SNP) | VAF 48/208 reads (23%) | called by muse, mutect2, varscan2
- NAV3 | c.5049C>A p.S1683= | Silent (SNP) | VAF 24/234 reads (10%) | called by muse, mutect2
- NFATC2 | c.903C>T p.A301= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as rs774678617; called by muse, mutect2, varscan2
- OR2F2 | c.246G>T p.L82= | Silent (SNP) | VAF 52/177 reads (29%) | called by muse, mutect2, varscan2
- OR4K1 | c.342G>A p.L114= | Silent (SNP) | VAF 68/153 reads (44%) | catalogued as rs755646328; called by muse, varscan2
- OR5B3 | c.231C>A p.P77= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as COSV58678090; called by muse, mutect2, varscan2
- OR8J3 | c.129G>T p.L43= | Silent (SNP) | VAF 68/331 reads (21%) | called by muse, varscan2
- PLEKHA6 | c.1233G>A p.E411= | Silent (SNP) | VAF 58/260 reads (22%) | called by muse, mutect2, varscan2
- PLXNA4 | c.2973G>A p.K991= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV100325028; called by muse, mutect2, varscan2
- PNRC1 | c.240C>T p.N80= | Silent (SNP) | VAF 100/424 reads (24%) | called by muse, mutect2, varscan2
- PRR23A | c.297G>C p.L99= | Silent (SNP) | VAF 22/282 reads (8%) | called by muse, mutect2
- RIPOR2 | c.2883G>A p.V961= | Silent (SNP) | VAF 30/213 reads (14%) | called by muse, mutect2, varscan2
- RYR2 | c.5259C>A p.L1753= | Silent (SNP) | VAF 47/199 reads (24%) | called by muse, mutect2, varscan2
- SALL3 | c.2721G>T p.P907= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as COSV73305928; called by muse, mutect2, varscan2
- SLC38A3 | c.339C>A p.S113= | Silent (SNP) | VAF 71/228 reads (31%) | called by muse, mutect2, varscan2
- SMG1 | c.9460C>T p.L3154= | Silent (SNP) | VAF 44/401 reads (11%) | called by muse, mutect2, varscan2
- SNTG2 | c.1386C>T p.L462= | Silent (SNP) | VAF 33/110 reads (30%) | called by muse, mutect2, varscan2
- SNX32 | c.534C>G p.L178= | Silent (SNP) | VAF 61/317 reads (19%) | catalogued as rs1256544812; called by muse, mutect2, varscan2
- SPATA17 | c.489A>T p.R163= | Silent (SNP) | VAF 36/179 reads (20%) | called by muse, mutect2, varscan2
- SVEP1 | c.714A>G p.P238= | Silent (SNP) | VAF 62/341 reads (18%) | called by muse, mutect2, varscan2
- SYNE3 | c.1569A>G p.A523= | Silent (SNP) | VAF 162/403 reads (40%) | called by muse, mutect2, varscan2
- TBC1D2 | c.2724A>G p.A908= (on ENST00000465784 / NM_001267571.2; = p.A897= on NM_018421.4) | Silent (SNP) | VAF 109/434 reads (25%) | called by muse, mutect2, varscan2
- TRANK1 | c.1905C>T p.L635= | Silent (SNP) | VAF 95/338 reads (28%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.2115C>T p.S705= | Silent (SNP) | VAF 103/356 reads (29%) | catalogued as rs754123865; called by muse, mutect2, varscan2
- TTN | c.23043G>T p.L7681= (on ENST00000591111; = p.L6754= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- USP44 | c.1080A>T p.A360= | Silent (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- VCL | c.495G>A p.G165= | Silent (SNP) | VAF 78/315 reads (25%) | called by muse, mutect2, varscan2
- ZNF827 | c.1599C>A p.P533= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as COSV101061119; called by muse, mutect2, varscan2
- AC107023.1 | chr12:40445583 A>G | 5'Flank (SNP) | VAF 36/206 reads (17%) | called by muse, varscan2
- AMPH | c.1183-1358G>A | Intron (SNP) | VAF 46/134 reads (34%) | catalogued as rs1391678569; called by muse, mutect2, varscan2
- ANKRD30BL | c.614+987A>G | Intron (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- ARMC8 | c.1134+23C>T | Intron (SNP) | VAF 80/335 reads (24%) | called by muse, mutect2, varscan2
- BIRC8 | n.1134T>G | RNA (SNP) | VAF 59/248 reads (24%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+3527G>A | Intron (SNP) | VAF 59/190 reads (31%) | catalogued as rs1239144133; called by muse, mutect2, varscan2
- C22orf34 | n.797G>T | RNA (SNP) | VAF 14/136 reads (10%) | called by muse, mutect2
- CAPN1 | chr11:65181289 G>A | 5'Flank (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- CD1A | c.*32C>A | 3'UTR (SNP) | VAF 13/86 reads (15%) | catalogued as COSV99192582; called by muse, mutect2, varscan2
- CEACAM16 | c.-34G>A | 5'UTR (SNP) | VAF 61/319 reads (19%) | catalogued as rs79655389, COSV104434871; called by muse, mutect2, varscan2
- CIB2 | c.*35A>G | 3'UTR (SNP) | VAF 66/209 reads (32%) | called by muse, mutect2, varscan2
- DPPA4 | c.*23C>A | 3'UTR (SNP) | VAF 56/166 reads (34%) | called by muse, mutect2, varscan2
- DTNBP1 | c.811+67G>C | Intron (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- EPB41L1 | c.1669-3042G>A | Intron (SNP) | VAF 40/284 reads (14%) | called by muse, mutect2, varscan2
- EPHA6 | c.2784+8141G>T | Intron (SNP) | VAF 8/206 reads (4%) | catalogued as rs1404979511; called by muse, mutect2
- EPS8 | c.736+13A>G | Intron (SNP) | VAF 56/408 reads (14%) | called by muse, mutect2, varscan2
- FAM193B | c.210+149G>T | Intron (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- FAM27E5 | n.364A>T | RNA (SNP) | VAF 40/379 reads (11%) | called by muse, mutect2, varscan2
- FBXO30 | chr6:145791382 A>G | 3'Flank (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2
- FGFR2 | c.454+21G>A | Intron (SNP) | VAF 42/309 reads (14%) | catalogued as rs751109931, COSV60638903; called by muse, mutect2, varscan2
- FSTL5 | c.-1delinsCA | 5'UTR (INS) | VAF 7/81 reads (9%) | called by mutect2*, pindel
- GCSAML | chr1:247549074 A>T | 5'Flank (SNP) | VAF 23/120 reads (19%) | called by muse, mutect2, varscan2
- GREB1L | c.2182+27C>G | Intron (SNP) | VAF 68/304 reads (22%) | called by muse, mutect2, varscan2
- HERC2P2 | n.2862G>A | RNA (SNP) | VAF 74/233 reads (32%) | catalogued as rs762197762; called by muse, mutect2, varscan2
- HES1 | c.205-84G>T | Intron (SNP) | VAF 35/258 reads (14%) | called by muse, mutect2, varscan2
- HLA-F-AS1 | n.1473T>A | RNA (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.9+363T>C | Intron (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- KCNIP4 | c.62-421170G>T | Intron (SNP) | VAF 18/151 reads (12%) | called by muse, varscan2
- LAMC3 | c.*70C>A | 3'UTR (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- LINC00602 | n.1115C>A | RNA (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- LINC01591 | n.418G>A | RNA (SNP) | VAF 12/93 reads (13%) | catalogued as rs181295694; called by muse, mutect2
- MECOM | c.-4G>C | 5'UTR (SNP) | VAF 97/373 reads (26%) | called by muse, mutect2, varscan2
- MEFV | c.*1003C>A | 3'UTR (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- MEMO1 | c.62-19792G>C | Intron (SNP) | VAF 38/110 reads (35%) | called by muse, mutect2, varscan2
- MGAM | c.4619-2664C>A | Intron (SNP) | VAF 23/140 reads (16%) | called by muse, mutect2, varscan2
- MIR519A1 | n.70A>T | RNA (SNP) | VAF 25/215 reads (12%) | called by muse, mutect2, varscan2
- MIR7-2 | n.15G>C | RNA (SNP) | VAF 28/200 reads (14%) | called by muse, mutect2, varscan2
- MYH2 | c.205-9G>T | Intron (SNP) | VAF 50/442 reads (11%) | called by muse, mutect2, varscan2
- NAV3 | c.2024-12710G>T | Intron (SNP) | VAF 48/340 reads (14%) | called by muse, mutect2, varscan2
- NRG3 | c.823+1911G>T | Intron (SNP) | VAF 27/71 reads (38%) | called by muse, varscan2
- OR11H2 | chr14:19712926 C>A | 3'Flank (SNP) | VAF 48/178 reads (27%) | called by muse, mutect2, varscan2
- OR52Z1 | n.349G>T | RNA (SNP) | VAF 29/126 reads (23%) | called by muse, mutect2, varscan2
- OR56A1 | c.*2T>C | 3'UTR (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- PPP1R9A | c.2757+775C>T | Intron (SNP) | VAF 41/263 reads (16%) | called by muse, mutect2, varscan2
- PRSS37 | c.176+395C>T | Intron (SNP) | VAF 19/133 reads (14%) | called by muse, mutect2, varscan2
- PRX | c.381+17C>A | Intron (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- RANBP17 | c.2231+73A>T | Intron (SNP) | VAF 105/337 reads (31%) | called by muse, mutect2, varscan2
- REG1B | c.433+54G>T | Intron (SNP) | VAF 34/174 reads (20%) | catalogued as rs1222382863, COSV59306056; called by muse, mutect2, varscan2
- SCAND1 | c.-111C>A | 5'UTR (SNP) | VAF 37/227 reads (16%) | called by muse, mutect2, varscan2
- SEMA5A | c.*40C>T | 3'UTR (SNP) | VAF 45/285 reads (16%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.3025C>A | RNA (SNP) | VAF 65/514 reads (13%) | called by muse, mutect2, varscan2
- SPTLC2 | c.482+15G>A | Intron (SNP) | VAF 109/257 reads (42%) | called by muse, mutect2, varscan2
- TMCO1 | c.*1026G>T | 3'UTR (SNP) | VAF 22/120 reads (18%) | called by muse, mutect2, varscan2
- TMEM135 | c.*6827G>A | 3'UTR (SNP) | VAF 57/243 reads (23%) | called by muse, mutect2, varscan2
- TRAV18 | c.-1C>A | 5'UTR (SNP) | VAF 126/255 reads (49%) | catalogued as rs1420282100; called by muse, mutect2, varscan2
- TRDN | c.793+24G>C | Intron (SNP) | VAF 45/194 reads (23%) | called by muse, varscan2
- UQCRB | c.*969G>T | 3'UTR (SNP) | VAF 96/234 reads (41%) | called by mutect2, varscan2
- ZFP28 | c.898+31C>T | Intron (SNP) | VAF 76/384 reads (20%) | catalogued as COSV100019841; called by muse, mutect2, varscan2
- ZNF41 | chrX:47483621 G>T | 5'Flank (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- ZNF451 | c.186+2278_186+2280del | Intron (DEL) | VAF 29/126 reads (23%) | called by mutect2, pindel, varscan2
- ZNF658B | n.2041C>A | RNA (SNP) | VAF 92/511 reads (18%) | called by muse, mutect2, varscan2
